CCDI case PBBYPM — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/8bcab757-70d8-43d1-9ed0-87cb6c998162

Demographics
Sex at birth: male; Race: white; Vital status: Alive.

Diagnoses (1)
1. Germinoma: ICD-O-3 morphology code: 9064/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 8.8 years (3,201 days).

Biospecimens (3 samples)
- Sample 0DL6RH: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DL6RR: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DL6S2: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
